Somatic mutation profile of tumor specimen TCGA-AB-2810-03B (aliquot TCGA-AB-2810-03B-01W-0728-08) from TCGA case TCGA-AB-2810, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.6 years (27,971 days).
Specimen TCGA-AB-2810-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7b6f91b-dfee-4299-a4cb-ddc76073e82f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2810-11B (Solid Tissue Normal), aliquot TCGA-AB-2810-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9b67683-d015-4b51-9ce9-480af487fb1d

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by mutect2, varscan2
- FCHSD1 | c.234G>A p.R78= | Splice Region (SNP) | VAF 20/45 reads (44%) | catalogued as COSV53353712; called by muse, mutect2, varscan2
- IRGC | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs773451234, COSV54985929, COSV54986267; called by mutect2, varscan2
- PPCS | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.822); catalogued as rs1158661768, COSV100999509; called by mutect2, varscan2
